Somatic mutation profile of tumor specimen ALCH-B2RM-TTP1-A (aliquot ALCH-B2RM-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2RM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.7 years (22,168 days).
Specimen ALCH-B2RM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34d77611-507c-450c-a3ed-bf24a32a7780.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RM-NB1-A (Blood Derived Normal), aliquot ALCH-B2RM-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9042631d-3504-4912-8e92-831e10ebf075

The open-access MAF lists 412 somatic variants for this specimen: 280 protein-altering or splice-affecting, 92 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 238, Silent 92, Nonsense Mutation 18, Intron 16, 3'UTR 9, Frame Shift Del 9, RNA 7, Splice Site 5, Frame Shift Ins 3, Splice Region 3, 3'Flank 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1907G>T p.G636V (on ENST00000288602 / NM_001374244.1; = p.G596V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/369 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs397507483, CM060877, COSV56105584, COSV99951808; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 90/252 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SNRPD3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV53183301, COSV53184122; called by muse, mutect2, varscan2
- ADAMTS12 | c.3788C>T p.T1263M | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs757177041, COSV100710420, COSV61263698; called by muse, mutect2, varscan2
- ADAMTS16 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 12/347 reads (3%) | catalogued as rs1315627534, COSV99943449; called by muse, mutect2
- ADGRB3 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65392703; called by muse, mutect2, varscan2
- AFTPH | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV53221133, COSV99480966; called by muse, mutect2, varscan2
- AGRN | c.3923G>A p.R1308H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs771823174; called by muse, mutect2, varscan2
- ANK2 | c.2273C>A p.T758N | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100005128, COSV52151735; called by muse, mutect2, varscan2
- ANKK1 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.262); catalogued as rs762261977, COSV58274315; called by muse, mutect2, varscan2
- ANKRD17 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100430122; called by muse, mutect2, varscan2
- AP2B1 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV52001300; called by muse, mutect2, varscan2
- CACNA1I | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1313739182, COSV60804712; called by muse, mutect2, varscan2
- CDH5 | c.2030C>A p.A677E | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.05); catalogued as rs1201962235; called by muse, mutect2, varscan2
- CFAP77 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753048163; called by muse, mutect2
- CMTR1 | c.2301G>T p.K767N | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV64982180; called by muse, mutect2
- CNOT1 | c.5458A>G p.M1820V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55319701; called by muse, mutect2
- CNTN5 | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248802172; called by muse, mutect2
- CNTN6 | c.2231G>T p.G744V | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100611560, COSV63191186; called by muse, mutect2, varscan2
- CRACD | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs528871147, COSV51719395; called by muse, mutect2
- CRB1 | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 99/295 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV66347977; called by muse, mutect2, varscan2
- CRB2 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs761776501; called by muse, mutect2, varscan2
- DCAF4L2 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60476481; called by muse, mutect2, varscan2
- DCAF4L2 | c.760C>A p.R254S | Missense Mutation (SNP) | VAF 76/358 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60476643; called by muse, mutect2, varscan2
- DCDC1 | c.3509G>T p.R1170I (on ENST00000597505 / NM_001367979.1; = p.R277I on NM_020869.3) | Missense Mutation (SNP) | VAF 23/456 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV60311119; called by muse, mutect2
- DGKD | c.571G>A p.G191R (on ENST00000264057 / NM_152879.3; = p.G147R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs1342188918; called by muse, mutect2
- DNAH11 | c.1358G>T p.W453L | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749372718, COSV60962719; called by muse, mutect2, varscan2
- DNAH7 | c.5675A>G p.Q1892R | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs764237905; called by muse, mutect2, varscan2
- DYSF | c.4586G>T p.R1529L | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV50289003, COSV50367093; called by muse, mutect2, varscan2
- ERVV-1 | c.1186G>T p.G396C | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74082844; called by muse, mutect2, varscan2
- FANK1 | c.932del p.G311Afs*5 | Frame Shift Del (DEL) | VAF 78/321 reads (24%) | catalogued as COSV64133112; called by mutect2, pindel, varscan2
- GABRA5 | c.1375G>C p.A459P | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV59478163; called by muse, mutect2, varscan2
- HDAC11 | c.412+1G>T p.X138_splice | Splice Site (SNP) | VAF 92/307 reads (30%) | catalogued as COSV55474169; called by muse, mutect2, varscan2
- HEATR3 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756461740, COSV53529690, COSV99590069; called by muse, mutect2, varscan2
- HEATR5B | c.5507G>A p.R1836H | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs372733156; called by muse, mutect2, varscan2
- HSD17B3 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 75/337 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV64557417; called by muse, mutect2, varscan2
- HYDIN | c.13591C>A p.Q4531K | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV101125185; called by muse, mutect2, varscan2
- IQGAP2 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV57177499; called by muse, mutect2, varscan2
- ITK | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV68435270; called by muse, mutect2, varscan2
- KANSL1L | c.1742A>G p.Y581C | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs780884182; called by muse, mutect2, varscan2
- KIF1A | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57483959; called by muse, mutect2, varscan2
- KIF26B | c.4010C>G p.P1337R | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV100833713; called by muse, mutect2, varscan2
- KLHL26 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV56317389; called by muse, mutect2, varscan2
- KLHL33 | c.935G>T p.R312L | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104419496; called by muse, mutect2, varscan2
- KLHL4 | c.842C>G p.P281R | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64139911; called by muse, mutect2, varscan2
- LEPR | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV60765228; called by muse, mutect2, varscan2
- LRRC66 | c.858G>T p.G286= | Splice Region (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100602817; called by muse, mutect2, varscan2
- MAK | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 23/389 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs1342981896; called by muse, mutect2
- MAP2K3 | c.416G>T p.C139F (on ENST00000342679 / NM_145109.3; = p.C110F on NM_002756.4) | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as rs1314519598, COSV100383724; called by muse, mutect2
- MED23 | c.2519del p.G840Vfs*26 | Frame Shift Del (DEL) | VAF 52/227 reads (23%) | catalogued as rs867066416; called by mutect2, pindel, varscan2
- MEOX2 | c.219C>A p.H73Q | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100012552; called by muse, varscan2
- MGAM | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101516593; called by muse, mutect2, varscan2
- MIER2 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV53394562; called by muse, mutect2, varscan2
- MNAT1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54188332; called by muse, mutect2, varscan2
- MUC16 | c.40198G>T p.D13400Y | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV66694420; called by muse, mutect2, varscan2
- MUC16 | c.5909C>A p.P1970Q | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV101200652; called by muse, mutect2, varscan2
- NEB | c.9046C>T p.R3016* | Nonsense Mutation (SNP) | VAF 42/450 reads (9%) | catalogued as rs1301228529; called by muse, mutect2
- NFX1 | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs914982082; called by muse, mutect2, varscan2
- NR2F1 | c.328T>A p.F110I | Missense Mutation (SNP) | VAF 162/640 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD160985; called by muse, mutect2, varscan2
- NTRK3 | c.1996G>T p.G666C | Missense Mutation (SNP) | VAF 100/319 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62301349; called by muse, mutect2, varscan2
- OAS3 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 114/444 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as rs765569593; called by muse, mutect2, varscan2
- OR2A25 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV68717067; called by muse, mutect2, varscan2
- OR4K2 | c.779G>T p.W260L | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53850825; called by muse, mutect2, varscan2
- OR4K2 | c.780G>T p.W260C | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs1378426875; called by muse, mutect2, varscan2
- PABPC3 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1415474806; called by muse, mutect2, varscan2
- PCNT | c.5143G>A p.E1715K | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs1269435393; called by muse, mutect2, varscan2
- PDGFRB | c.366T>C p.D122= | Splice Region (SNP) | VAF 9/42 reads (21%) | catalogued as rs200535821; called by muse, mutect2
- PROS1 | c.1155G>T p.M385I | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs199469492, CM136311, CS951518; called by muse, mutect2, varscan2
- RABGAP1L | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52290841; called by muse, mutect2, varscan2
- RECQL4 | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.076); catalogued as rs750118023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMBP2 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 71/326 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV55465016; called by muse, mutect2, varscan2
- ROMO1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1436628196; called by muse, mutect2, varscan2
- RUNX1T1 | c.1811G>T p.R604L (on ENST00000265814 / NM_001198628.1; = p.R577L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs577506995; called by muse, varscan2
- SCN3A | c.5845C>A p.L1949I | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV99325843; called by muse, mutect2, varscan2
- SLIT2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs574995128; called by muse, mutect2, varscan2
- SLITRK2 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157838, COSV59425737; called by muse, mutect2, varscan2
- SPTA1 | c.2842C>T p.L948F | Missense Mutation (SNP) | VAF 84/485 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780450572; called by muse, mutect2, varscan2
- SYCP2L | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.587); catalogued as COSV51649918; called by muse, mutect2, varscan2
- TBX5 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 150/635 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557183241, COSV59862979; called by muse, mutect2, varscan2
- TDRD5 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 99/519 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867687242, COSV54242060; called by muse, mutect2, varscan2
- THSD1 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as rs777478888; called by muse, varscan2
- THSD1 | c.1699G>T p.A567S | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.272); catalogued as COSV51627787; called by muse, varscan2
- THSD7B | c.3405G>T p.W1135C (on ENST00000272643; = p.W1133C on NM_001316349.2) | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55695507, COSV55709258; called by muse, mutect2, varscan2
- TLR5 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 82/567 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV100643434, COSV60558883; called by muse, mutect2, varscan2
- TMCC3 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54155510; called by muse, mutect2, varscan2
- TRIM77 | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.836); catalogued as rs1253783454, COSV101242270; called by muse, mutect2
- TSPAN5 | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59878776; called by muse, mutect2, varscan2
- TTLL3 | c.1708G>C p.G570R | Missense Mutation (SNP) | VAF 71/365 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758674237; called by muse, mutect2, varscan2
- UGT2B15 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs142432791, COSV100592161; called by muse, mutect2
- USH2A | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs368754739; called by muse, mutect2, varscan2
- XKR9 | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV68773388; called by muse, mutect2, varscan2
- ZNF845 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV72004285; called by muse, mutect2
- ABCB11 | c.150+1G>C p.X50_splice | Splice Site (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- ABCB8 | c.448del p.V150* (on ENST00000297504 / NM_001282291.2; = p.V133* on NM_007188.5) | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- ABCC11 | c.3635A>T p.E1212V | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ABI3BP | c.3065C>A p.T1022N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAN | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ACTR3B | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ADAM29 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.02); called by muse, varscan2
- ADAMTSL3 | c.4029T>A p.N1343K | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ANO4 | c.1858G>T p.G620* (on ENST00000392977 / NM_001286615.2; = p.G585* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 34/245 reads (14%) | called by muse, mutect2, varscan2
- ANTXRL | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ARHGEF28 | c.4012G>C p.D1338H | Missense Mutation (SNP) | VAF 74/377 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATXN2 | c.2859G>T p.Q953H (on ENST00000550104; = p.Q793H on NM_002973.4) | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- BAZ2B | c.3152T>C p.L1051S | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- BMP10 | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRS3 | c.1172G>T p.S391I | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.08); called by muse, mutect2
- CACNA1E | c.2467C>A p.H823N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CACNB2 | c.329C>A p.A110E (on ENST00000324631 / NM_201596.3; = p.A55E on NM_000724.4) | Missense Mutation (SNP) | VAF 124/478 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CARD11 | c.2169G>T p.R723S | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPERG | c.1432A>T p.K478* | Nonsense Mutation (SNP) | VAF 51/300 reads (17%) | called by muse, mutect2, varscan2
- CCDC160 | c.363T>A p.S121R | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- CCR3 | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CDCP1 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK8 | c.107A>T p.Y36F | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHMP4B | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 66/444 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CHRM1 | c.410G>C p.R137P | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRNB2 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 30/586 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CHRNB3 | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 128/557 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CNTN6 | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CNTN6 | c.2230G>T p.G744C | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL19A1 | c.2026_2027del p.P676Rfs*2 | Frame Shift Del (DEL) | VAF 26/165 reads (16%) | called by mutect2, pindel, varscan2
- COL19A1 | c.3184G>C p.D1062H | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A2 | c.2553G>T p.K851N | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CORO7 | c.2305G>T p.E769* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- CREBBP | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CUX2 | c.2834C>A p.T945K | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYBB | c.1273T>A p.Y425N | Missense Mutation (SNP) | VAF 15/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP4F12 | c.275T>A p.L92Q | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DCX | c.696T>G p.D232E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DNAH14 | c.4213T>A p.S1405T (on ENST00000445597; = p.S1810T on NM_001367479.1) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DNAH8 | c.7093G>C p.E2365Q | Missense Mutation (SNP) | VAF 95/656 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAI1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 164/551 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DOCK10 | c.3026A>T p.N1009I | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- DPF2 | c.965G>T p.W322L | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EIF1 | c.239_240insT p.E81Rfs*8 | Frame Shift Ins (INS) | VAF 54/222 reads (24%) | called by mutect2, pindel, varscan2
- EIF3I | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EPB41L3 | c.530-1G>T p.X177_splice | Splice Site (SNP) | VAF 36/146 reads (25%) | called by muse, mutect2, varscan2
- ESR2 | c.1317G>A p.W439* | Nonsense Mutation (SNP) | VAF 50/282 reads (18%) | called by muse, mutect2, varscan2
- ESR2 | c.1316G>A p.W439* | Nonsense Mutation (SNP) | VAF 48/282 reads (17%) | called by muse, mutect2, varscan2
- EXOC1 | c.107G>T p.C36F | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- EYA1 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 74/285 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- FAM71B | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 86/410 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBLN2 | c.2764G>T p.G922C | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO8 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- FGR | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FLG | c.8096C>T p.S2699L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by mutect2, varscan2
- FMO2 | c.1340C>A p.P447Q | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FUT8 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); called by muse, mutect2
- GALNT13 | c.398G>T p.R133I | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAP43 | c.135C>A p.H45Q | Missense Mutation (SNP) | VAF 90/339 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAS2L2 | c.2361G>T p.R787S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- GYPC | c.118G>T p.G40W | Missense Mutation (SNP) | VAF 70/430 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- HIP1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HTR1F | c.682del p.Q228Kfs*20 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- HTR3A | c.1095G>T p.R365S | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IZUMO3 | c.646G>T p.V216L (on ENST00000543880 / NM_001365008.2; = p.V210L on NM_001271706.1) | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- JUP | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 18/578 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- KANK4 | c.248del p.P83Lfs*43 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | called by mutect2, varscan2
- KCNA6 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KEL | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 90/611 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- KIF15 | c.460-2A>T p.X154_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- KIF27 | c.1933_1947del p.N645_E649del | In Frame Del (DEL) | VAF 29/156 reads (19%) | called by mutect2, pindel, varscan2
- KIF2B | c.439T>C p.S147P | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KIF2B | c.1190T>G p.V397G | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- KIFC3 | c.2146G>T p.G716C | Missense Mutation (SNP) | VAF 108/402 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- KLRF1 | c.424T>A p.C142S | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KNG1 | c.1408G>T p.G470C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- KPNA7 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- KTI12 | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- LGR5 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LRP1B | c.7874G>T p.C2625F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LTBP3 | c.3007G>C p.E1003Q | Missense Mutation (SNP) | VAF 109/453 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- LYST | c.2521G>T p.G841W | Missense Mutation (SNP) | VAF 205/594 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MAEL | c.279T>G p.N93K | Missense Mutation (SNP) | VAF 14/444 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.022); called by muse, mutect2
- MAP2K3 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 50/614 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.102); called by muse, mutect2
- MEFV | c.2114C>A p.P705H | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MGA | c.1753A>T p.R585* | Nonsense Mutation (SNP) | VAF 37/107 reads (35%) | called by muse, mutect2, varscan2
- MINDY4B | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLIP | c.1114-2A>T p.X372_splice | Splice Site (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2
- MON1B | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 60/372 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC12 | c.2336G>T p.S779I (on ENST00000379442; = p.S636I on NM_001164462.1) | Missense Mutation (SNP) | VAF 147/788 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MUC12 | c.14554G>C p.A4852P (on ENST00000379442; = p.A4709P on NM_001164462.1) | Missense Mutation (SNP) | VAF 139/527 reads (26%) | SIFT tolerated, low confidence (0.27); called by muse, mutect2, varscan2
- MUC16 | c.36262G>T p.E12088* | Nonsense Mutation (SNP) | VAF 20/415 reads (5%) | called by muse, mutect2
- MYH4 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- MYOM1 | c.3259T>A p.W1087R | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFS1 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 101/364 reads (28%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- NEK1 | c.575T>A p.V192D | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLGN1 | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP2 | c.3152G>T p.W1051L | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2
- NOBOX | c.1010C>A p.T337K | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- NTRK3 | c.1228T>G p.F410V | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPA3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10G7 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4A5 | c.948G>T p.*316Yext*17 | Nonstop Mutation (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- OR5K2 | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR5T1 | c.904T>C p.Y302H | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- OR9G4 | c.783G>T p.R261S | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- OTOG | c.4283G>T p.R1428L | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- PADI6 | c.1352C>A p.A451D | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDH1 | c.2074G>T p.V692F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); called by muse, mutect2
- PCDH11X | c.3034C>T p.P1012S | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH17 | c.1045_1046insG p.P349Rfs*30 | Frame Shift Ins (INS) | VAF 77/364 reads (21%) | called by pindel, varscan2
- PCDHGA7 | c.2204T>C p.V735A | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDZD8 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIGV | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PLCB3 | c.2237A>T p.Y746F | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- POGK | c.739A>T p.M247L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- POM121L12 | c.717C>A p.S239R | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PPP4C | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PPP4R3C | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- PRAG1 | c.2794G>T p.G932W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PRAMEF27 | c.61A>T p.R21W | Missense Mutation (SNP) | VAF 63/563 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PRRG1 | c.168A>T p.K56N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- PRSS55 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 112/442 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PRUNE2 | c.4432G>T p.G1478C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRUNE2 | c.3525G>C p.W1175C | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRUNE2 | c.3524G>A p.W1175* | Nonsense Mutation (SNP) | VAF 35/157 reads (22%) | called by muse, mutect2, varscan2
- PTCH2 | c.2483G>T p.G828V | Missense Mutation (SNP) | VAF 109/472 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RABGAP1L | c.1786G>T p.G596* | Nonsense Mutation (SNP) | VAF 54/191 reads (28%) | called by muse, mutect2, varscan2
- RASGRP2 | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RBM33 | c.1871A>T p.Q624L | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, varscan2
- RC3H1 | c.2395G>T p.A799S | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RFX3 | c.797A>T p.Q266L | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- RGS9 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 36/826 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.237); called by muse, mutect2
- RHOBTB1 | c.1692C>A p.N564K | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- RIC1 | c.484G>T p.G162* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- RIMS2 | c.3220C>A p.P1074T (on ENST00000666250 / NM_001348490.2; = p.P882T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RNF103 | c.1478T>A p.L493* | Nonsense Mutation (SNP) | VAF 51/204 reads (25%) | called by muse, mutect2, varscan2
- RNF214 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 39/227 reads (17%) | called by muse, mutect2, varscan2
- RYR2 | c.12333C>A p.N4111K | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SEPTIN14 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, varscan2
- SERPINA5 | c.1099G>T p.G367W | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SFSWAP | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SIDT1 | c.2469G>T p.Q823H | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SIPA1L3 | c.2998G>T p.G1000C | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC2A10 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 30/588 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- SLC6A15 | c.1696A>T p.S566C | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- SLC6A7 | c.971T>A p.F324Y | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SMYD3 | c.1195A>G p.I399V (on ENST00000490107 / NM_001375962.1; = p.I340V on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2
- SNRPA1 | c.265T>C p.C89R | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- STK32C | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STN1 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.247); called by muse, varscan2
- STXBP5 | c.1650G>C p.E550D | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- SUSD1 | c.108_113del p.L36_V38delinsF | In Frame Del (DEL) | VAF 27/163 reads (17%) | called by mutect2, pindel, varscan2
- SYT14 | c.1622C>A p.S541* | Nonsense Mutation (SNP) | VAF 130/709 reads (18%) | called by muse, mutect2, varscan2
- TBR1 | c.2020G>T p.G674C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2
- TELO2 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- TEX33 | c.368C>A p.P123H (on ENST00000381821 / NM_001163857.2; = p.P38H on NM_178552.4) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- TFDP2 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- THEM6 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD7B | c.3406G>T p.G1136* (on ENST00000272643; = p.G1134* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- TICRR | c.5366G>C p.R1789T | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TPRX1 | c.800del p.G267Afs*22 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | called by mutect2, pindel, varscan2
- TRGV4 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 62/496 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM3 | c.1721G>T p.R574L | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- TRIM58 | c.586_587insT p.E196Vfs*40 | Frame Shift Ins (INS) | VAF 81/495 reads (16%) | called by mutect2, pindel, varscan2
- TRPM3 | c.4981A>G p.S1661G (on ENST00000357533 / NM_001366142.2; = p.S1516G on NM_020952.6) | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TSEN34 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 61/238 reads (26%) | called by muse, mutect2, varscan2
- TTC29 | c.888C>G p.V296= | Splice Region (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- TTC6 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TTN | c.54524del p.P18175Qfs*3 (on ENST00000591111; = p.P10751Qfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 46/236 reads (19%) | called by mutect2, pindel, varscan2
- TTN | c.48058G>C p.V16020L (on ENST00000591111; = p.V8596L on NM_003319.4) | Missense Mutation (SNP) | VAF 106/391 reads (27%) | PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TTN | c.21956del p.P7319Qfs*61 (on ENST00000591111; = p.P6392Qfs*61 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- UBN1 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2
- UBN2 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UEVLD | c.146A>C p.Q49P | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- UNC5D | c.1101T>G p.H367Q | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- UNCX | c.930C>A p.C310* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- USH2A | c.3179C>A p.P1060H | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- USP11 | c.523G>T p.G175C (on ENST00000218348; = p.G132C on NM_001371072.1) | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- USP43 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VSTM1 | c.493T>C p.S165P | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZFHX4 | c.10118C>A p.A3373D | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ZFP30 | c.504A>T p.R168S | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF107 | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZNF155 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF441 | c.1448C>A p.A483E | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- ZNF462 | c.1363T>A p.S455T | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF469 | c.11456C>A p.T3819N (on ENST00000437464; = p.T3847N on NM_001367624.2) | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ABI3 | c.399C>A p.L133= | Silent (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- ACOT12 | c.600A>T p.T200= | Silent (SNP) | VAF 35/194 reads (18%) | called by muse, mutect2, varscan2
- ANK2 | c.2274C>A p.T758= | Silent (SNP) | VAF 72/365 reads (20%) | called by muse, mutect2, varscan2
- ARAF | c.414C>A p.S138= | Silent (SNP) | VAF 18/304 reads (6%) | called by muse, mutect2
- ASH1L | c.5802G>A p.E1934= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- ASTN2 | c.2616C>T p.T872= (on ENST00000313400 / NM_001365069.1; = p.T821= on NM_014010.5) | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as rs1481264302; called by muse, mutect2, varscan2
- CACNA1S | c.4035C>A p.A1345= | Silent (SNP) | VAF 178/487 reads (37%) | called by muse, mutect2, varscan2
- CADPS | c.1350C>A p.S450= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- CFAP99 | c.438G>A p.Q146= (on ENST00000506607; = p.Q699= on NM_001193282.3) | Silent (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- CHL1 | c.2451G>T p.G817= (on ENST00000397491 / NM_001253387.1; = p.G833= on NM_006614.4) | Silent (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- CHRDL1 | c.381C>T p.L127= (on ENST00000372045; = p.L133= on NM_145234.4) | Silent (SNP) | VAF 62/243 reads (26%) | called by muse, mutect2, varscan2
- CLEC4G | c.771C>T p.D257= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV61003812; called by muse, mutect2, varscan2
- CNTN5 | c.2022T>A p.P674= | Silent (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2
- CYP11B1 | c.432G>A p.L144= | Silent (SNP) | VAF 201/634 reads (32%) | catalogued as COSV52830748; called by muse, mutect2, varscan2
- DGKI | c.2589G>C p.A863= | Silent (SNP) | VAF 73/279 reads (26%) | catalogued as COSV99935784; called by muse, mutect2, varscan2
- FAM186B | c.1113T>A p.L371= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- FAM81B | c.159G>T p.A53= | Silent (SNP) | VAF 80/327 reads (24%) | called by muse, mutect2, varscan2
- FAT2 | c.11247C>A p.P3749= | Silent (SNP) | VAF 38/137 reads (28%) | called by muse, mutect2, varscan2
- FAT3 | c.11718C>A p.G3906= | Silent (SNP) | VAF 34/156 reads (22%) | called by muse, mutect2, varscan2
- FOXG1 | c.1137C>A p.L379= | Silent (SNP) | VAF 130/552 reads (24%) | called by mutect2, varscan2
- FOXO1 | c.279G>T p.A93= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- FSIP2 | c.7485T>C p.Y2495= | Silent (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- GCGR | c.1182G>T p.L394= | Silent (SNP) | VAF 58/218 reads (27%) | called by muse, varscan2
- GIMAP1 | c.142C>T p.L48= | Silent (SNP) | VAF 53/274 reads (19%) | called by muse, mutect2, varscan2
- GRK1 | c.1257C>T p.F419= | Silent (SNP) | VAF 16/428 reads (4%) | called by muse, mutect2
- GRM7 | c.2508G>C p.A836= | Silent (SNP) | VAF 96/469 reads (20%) | catalogued as rs750777601, COSV63171957; called by muse, mutect2, varscan2
- IGHD | c.240C>A p.G80= | Silent (SNP) | VAF 123/464 reads (27%) | catalogued as rs377700034; called by muse, mutect2, varscan2
- IGHV3-7 | c.69G>T p.L23= | Silent (SNP) | VAF 50/370 reads (14%) | called by muse, varscan2
- IL17B | c.100C>A p.R34= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV55783132; called by muse, varscan2
- KCNA4 | c.1518C>A p.T506= | Silent (SNP) | VAF 52/294 reads (18%) | catalogued as COSV100069095, COSV60253842; called by muse, mutect2, varscan2
- KCTD8 | c.693T>C p.R231= | Silent (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- KIAA2013 | c.1770G>T p.L590= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs374964106; called by muse, mutect2, varscan2
- KIF2B | c.1191G>T p.V397= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as COSV52128847; called by muse, mutect2, varscan2
- LCT | c.3624G>A p.T1208= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs769747422, COSV51556616; called by muse, mutect2, varscan2
- LHX8 | c.114C>A p.P38= | Silent (SNP) | VAF 6/41 reads (15%) | called by mutect2, varscan2
- LRP1B | c.8566C>A p.R2856= | Silent (SNP) | VAF 41/220 reads (19%) | catalogued as rs749243132, COSV67229298; called by muse, mutect2, varscan2
- MAGI2 | c.786T>G p.G262= | Silent (SNP) | VAF 16/278 reads (6%) | called by muse, mutect2
- MATK | c.621G>T p.L207= (on ENST00000310132 / NM_139355.3; = p.L208= on NM_002378.4) | Silent (SNP) | VAF 94/375 reads (25%) | called by muse, mutect2, varscan2
- MDGA1 | c.417G>C p.T139= | Silent (SNP) | VAF 61/131 reads (47%) | called by muse, mutect2, varscan2
- MGME1 | c.132T>C p.Y44= | Silent (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- MISP | c.471C>A p.T157= | Silent (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- MRC1 | c.3234A>T p.I1078= | Silent (SNP) | VAF 218/810 reads (27%) | called by muse, mutect2, varscan2
- MTNR1B | c.357G>T p.V119= | Silent (SNP) | VAF 120/514 reads (23%) | catalogued as rs568002248; called by muse, mutect2, varscan2
- NCOR2 | c.4770T>A p.R1590= | Silent (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- NCOR2 | c.4290C>T p.R1430= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as rs371027420; called by muse, mutect2, varscan2
- NFATC2 | c.855C>T p.P285= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV101044909; called by muse, mutect2, varscan2
- NR2C2AP | c.192C>A p.I64= | Silent (SNP) | VAF 57/297 reads (19%) | called by muse, mutect2, varscan2
- NWD1 | c.1884C>A p.P628= | Silent (SNP) | VAF 73/366 reads (20%) | called by muse, mutect2, varscan2
- OBSCN | c.18307C>T p.L6103= | Silent (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- OLFML1 | c.66G>C p.P22= | Silent (SNP) | VAF 55/272 reads (20%) | called by muse, mutect2, varscan2
- OR4A5 | c.555A>C p.A185= | Silent (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- OR4D10 | c.778C>A p.R260= | Silent (SNP) | VAF 52/209 reads (25%) | called by muse, mutect2, varscan2
- OR56B4 | c.675T>A p.A225= | Silent (SNP) | VAF 60/278 reads (22%) | called by muse, mutect2, varscan2
- OR9I1 | c.106C>T p.L36= | Silent (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- PCDH17 | c.1119G>C p.L373= | Silent (SNP) | VAF 54/205 reads (26%) | called by muse, varscan2
- PCDH7 | c.2583C>A p.L861= | Silent (SNP) | VAF 68/357 reads (19%) | called by muse, mutect2, varscan2
- PCDHB1 | c.2151G>A p.K717= | Silent (SNP) | VAF 42/160 reads (26%) | called by muse, mutect2, varscan2
- PCDHB3 | c.1806G>C p.L602= | Silent (SNP) | VAF 115/620 reads (19%) | catalogued as rs782177805; called by muse, varscan2
- PDZRN3 | c.1917G>T p.P639= | Silent (SNP) | VAF 91/358 reads (25%) | catalogued as rs763622913, COSV55208270; called by muse, mutect2, varscan2
- PLAA | c.1428G>T p.R476= | Silent (SNP) | VAF 63/284 reads (22%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.1932G>A p.L644= | Silent (SNP) | VAF 25/208 reads (12%) | called by muse, mutect2, varscan2
- POLD1 | c.1992C>T p.L664= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs1057522746; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEG | c.186C>A p.G62= | Silent (SNP) | VAF 88/708 reads (12%) | called by muse, varscan2
- POTEM | c.186C>A p.G62= | Silent (SNP) | VAF 100/563 reads (18%) | catalogued as COSV69152629; called by muse, varscan2
- RASAL3 | c.795C>A p.T265= | Silent (SNP) | VAF 58/192 reads (30%) | called by muse, mutect2, varscan2
- REST | c.78G>T p.L26= | Silent (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- RIMS2 | c.3219C>A p.A1073= (on ENST00000666250 / NM_001348490.2; = p.A881= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 46/156 reads (29%) | called by muse, mutect2, varscan2
- RP1 | c.375G>T p.R125= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- SETD2 | c.1200A>T p.R400= | Silent (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- SLC39A5 | c.603G>A p.P201= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as rs61731625; called by muse, mutect2
- SLITRK2 | c.1557G>A p.P519= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs370329497; called by muse, mutect2
- SPATA7 | c.378A>T p.S126= | Silent (SNP) | VAF 52/216 reads (24%) | called by muse, mutect2, varscan2
- TAFA1 | c.12C>G p.V4= | Silent (SNP) | VAF 56/221 reads (25%) | called by muse, mutect2
- TENM1 | c.5151C>A p.T1717= | Silent (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- TLR4 | c.2353C>T p.L785= (on ENST00000355622 / NM_138554.5; = p.L745= on NM_003266.4) | Silent (SNP) | VAF 13/226 reads (6%) | called by muse, mutect2
- TMEM178B | c.771G>C p.G257= | Silent (SNP) | VAF 53/213 reads (25%) | called by muse, mutect2, varscan2
- TP53TG3D | c.285T>C p.C95= | Silent (SNP) | VAF 152/247 reads (62%) | catalogued as rs1278146084; called by mutect2, varscan2
- TREX2 | c.24C>G p.L8= | Silent (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- TRIML1 | c.1053C>A p.T351= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- TRIML2 | c.339C>T p.L113= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as COSV100455873; called by muse, mutect2, varscan2
- TSGA10IP | c.357C>T p.V119= | Silent (SNP) | VAF 61/217 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.24921C>T p.A8307= (on ENST00000591111; = p.A7380= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV60078821; called by muse, mutect2, varscan2
- TUBB2B | c.184C>A p.R62= | Silent (SNP) | VAF 169/513 reads (33%) | catalogued as COSV52533187; called by muse, mutect2, varscan2
- USH2A | c.4482T>C p.N1494= | Silent (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- UTP6 | c.1113A>G p.Q371= | Silent (SNP) | VAF 30/216 reads (14%) | catalogued as rs376977101; called by muse, mutect2, varscan2
- VWA3A | c.1461G>C p.R487= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100241179; called by muse, mutect2, varscan2
- WDFY3 | c.3993G>T p.V1331= | Silent (SNP) | VAF 36/190 reads (19%) | catalogued as rs1284147265, COSV99885174; called by muse, mutect2, varscan2
- ZFR2 | c.2280G>C p.L760= | Silent (SNP) | VAF 25/199 reads (13%) | catalogued as rs1189064539; called by muse, mutect2, varscan2
- ZNF19 | c.1014C>T p.F338= | Silent (SNP) | VAF 47/158 reads (30%) | catalogued as rs1225685745; called by muse, mutect2, varscan2
- ZNF536 | c.858C>G p.R286= | Silent (SNP) | VAF 48/183 reads (26%) | catalogued as COSV62821537; called by muse, mutect2, varscan2
- ZNF608 | c.3663T>C p.S1221= | Silent (SNP) | VAF 29/114 reads (25%) | called by mutect2, varscan2
- ZNF98 | c.585A>T p.S195= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- ABCC13 | n.3965C>A | RNA (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- AC244517.10 | c.36-5010T>C | Intron (SNP) | VAF 90/443 reads (20%) | catalogued as rs1160673064; called by muse, mutect2, varscan2
- ADARB2 | c.101-147692T>A | Intron (SNP) | VAF 16/135 reads (12%) | catalogued as rs1437820985, COSV101184456; called by muse, mutect2, varscan2
- AGA | c.*271A>C | 3'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- BTD | c.*31G>A | 3'UTR (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- C11orf58 | c.319-917A>G | Intron (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- CAPS | chr19:5914218 C>T | 5'Flank (SNP) | VAF 10/204 reads (5%) | catalogued as rs1438716641; called by muse, mutect2
- CD36 | c.*19del | 3'UTR (DEL) | VAF 44/168 reads (26%) | catalogued as rs753334442; called by mutect2, varscan2
- CLK2P1 | n.1171G>C | RNA (SNP) | VAF 109/482 reads (23%) | called by mutect2, varscan2
- CUX2 | c.63+65835G>T | Intron (SNP) | VAF 41/201 reads (20%) | called by muse, mutect2, varscan2
- CXCL12 | c.*274A>G | 3'UTR (SNP) | VAF 33/283 reads (12%) | called by muse, mutect2, varscan2
- CYYR1 | c.-131G>C | 5'UTR (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- DCN | c.885+53C>A | Intron (SNP) | VAF 66/255 reads (26%) | called by muse, mutect2, varscan2
- DIP2C | c.85+39239A>C | Intron (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- DOCK2 | c.2800-48351C>G | Intron (SNP) | VAF 42/198 reads (21%) | called by muse, mutect2, varscan2
- DPP9 | c.2245-90G>T | Intron (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- EFHC1 | c.*2260C>G | 3'UTR (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2
- FHAD1 | c.4122+1646C>G | Intron (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- GABRG3 | c.1123-1912C>T | Intron (SNP) | VAF 73/229 reads (32%) | called by muse, mutect2, varscan2
- HOXA2 | c.391+87T>C | Intron (SNP) | VAF 26/71 reads (37%) | called by muse, varscan2
- HOXB3 | c.-159+40G>A | Intron (SNP) | VAF 15/445 reads (3%) | called by muse, mutect2
- ISCU | c.115-124G>A | Intron (SNP) | VAF 112/577 reads (19%) | called by muse, mutect2, varscan2
- KCNAB2 | c.*1351A>G | 3'UTR (SNP) | VAF 26/185 reads (14%) | catalogued as rs1418010143; called by muse, mutect2, varscan2
- KRT8 | c.*36G>T | 3'UTR (SNP) | VAF 64/252 reads (25%) | called by muse, mutect2, varscan2
- LDB3 | c.690-4826G>A | Intron (SNP) | VAF 35/124 reads (28%) | catalogued as rs200458194, COSV53943727, COSV99555687, COSV99555740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LY6K | c.-99C>A | 5'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as rs1462663356, COSV52832363; called by muse, mutect2
- MYADML | n.983A>C | RNA (SNP) | VAF 18/220 reads (8%) | catalogued as rs1432769499; called by muse, mutect2
- NCF1C | n.562C>T | RNA (SNP) | VAF 149/1138 reads (13%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1209G>T | RNA (SNP) | VAF 93/398 reads (23%) | called by mutect2, varscan2
- NPAS3 | c.733+4265T>A | Intron (SNP) | VAF 52/223 reads (23%) | called by muse, mutect2, varscan2
- OR4N3P | n.486C>G | RNA (SNP) | VAF 10/96 reads (10%) | called by mutect2, varscan2
- PCDHB6 | chr5:141156779 G>T | 3'Flank (SNP) | VAF 58/216 reads (27%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157665 C>A | 3'Flank (SNP) | VAF 133/631 reads (21%) | called by mutect2, varscan2
- RFX5 | c.473+22G>A | Intron (SNP) | VAF 63/361 reads (17%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159635 G>T | 5'Flank (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- SH2D4A | c.*2A>T | 3'UTR (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- SNORD114-31 | chr14:100990082 G>T | 5'Flank (SNP) | VAF 61/302 reads (20%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133554668 G>C | 3'Flank (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- TPRXL | n.1253dup | RNA (INS) | VAF 8/81 reads (10%) | called by mutect2, pindel
- ZNF777 | c.*236G>A | 3'UTR (SNP) | VAF 56/225 reads (25%) | catalogued as rs986479969, COSV99925275; called by muse, mutect2, varscan2
